Somatic mutation profile of tumor specimen 0DPQRS from CCDI case PBCEDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (447 days).
Specimen 0DPQRS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f107053-a4da-44e1-bb0d-0fd669350d6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQRQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab84fa8-0561-4d5e-acf6-2d6713d7825a

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.503A>C p.H168P | Missense Mutation (SNP) | VAF 267/368 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52676197, COSV52682212, COSV52698349, COSV52762255; called by muse, mutect2, varscan2
- CABIN1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 84/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs145607829, COSV54077586; called by muse, mutect2, varscan2
- CD46 | c.78G>T p.L26F | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.986); catalogued as COSV59733341; called by muse, mutect2, varscan2
- SI | c.5390C>A p.P1797H | Missense Mutation (SNP) | VAF 124/1203 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV52267643; called by muse, mutect2, varscan2
- TOP2B | c.551A>G p.N184S (on ENST00000264331 / NM_001330700.2; = p.N179S on NM_001068.3) | Missense Mutation (SNP) | VAF 89/493 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244047807; called by muse, varscan2
- ZNF585B | c.1853A>T p.K618M | Missense Mutation (SNP) | VAF 92/635 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as rs1342088182; called by muse, mutect2, varscan2
- DPP9 | c.937C>T p.P313S (on ENST00000598800; = p.P342S on NM_139159.5) | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.086); called by muse, varscan2
- EGFR | c.3525C>A p.D1175E | Missense Mutation (SNP) | VAF 106/481 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FBXL16 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 102/187 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MMP14 | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 132/555 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NFATC2 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 149/569 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OR52E2 | c.509T>A p.F170Y | Missense Mutation (SNP) | VAF 110/405 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- OTOG | c.4702G>T p.A1568S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- SKOR1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 45/263 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTLL2 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 35/589 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.047); called by muse, mutect2
- ARL3 | c.87C>A p.G29= | Silent (SNP) | VAF 53/588 reads (9%) | called by muse, mutect2
- CADPS | c.2796C>T p.D932= | Silent (SNP) | VAF 126/688 reads (18%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.15G>A p.K5= | Silent (SNP) | VAF 317/847 reads (37%) | called by muse, mutect2
- USP48 | c.27G>A p.K9= | Silent (SNP) | VAF 36/372 reads (10%) | catalogued as rs769584018; called by muse, mutect2, varscan2
- ITSN2 | c.4257+79G>C | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
